Gene-level copy-number profile of tumor specimen TCGA-QR-A707-01A from TCGA case TCGA-QR-A707, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 43.4 years (15,870 days).
Specimen TCGA-QR-A707-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.7e3dbf5a-dfcc-4060-84c5-6a01e45c56b4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QR-A707-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS.
https://portal.gdc.cancer.gov/files/d156b19b-eb44-432d-bc05-0bc98f19d851

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 3,499; copy number 2: 54,115; copy number 3: 2,183; copy number 4: 7.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:56,718,789–56,819,696, 1 gene (within-gene range 0–1): FYB2.
- chr5:53,297,872–53,326,565, 1 gene: AC027329.1.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr8:139,108,430–139,127,953, 2 genes: AC100807.1, AC100807.2.
- chr11:22,445,673–22,492,073, 1 gene (within-gene range 0–2): LINC01495.
- chr16:52,198,012–52,227,956, 1 gene (within-gene range 0–2): AC007333.2.
- chr17:31,094,927–31,382,116, 1 gene (within-gene range 0–1): NF1.
- chr17:31,272,013–31,538,211, 7 genes (within-gene range 0–1): OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,443. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
